TCGA case TCGA-EK-A3GK — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d07d0a56-a25e-426b-8384-9d49e6545527

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 33 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, endocervical type: ICD-O-3 morphology code: 8384/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 33.4 years (12,207 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; AJCC pathologic T: T1b1; AJCC pathologic N: N0; AJCC pathologic M: MX; FIGO stage: Stage IB1; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 22; Lymphatic invasion present: Yes.

Follow-up (2 entries)
- Day 0 (preoperative): ECOG performance status: 0.
- Days to follow up: 15 days; Disease response: Tumor Free.

Molecular and laboratory tests
- Human Papillomavirus: Positive [Hpv strain: HPV16].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Current User; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Weight: 73 kg; Height: 165 cm; BMI: 26.8.
- Timepoint category: Prior to Diagnosis; Comorbidities: Human Papillomavirus Infection; Risk factors: Human Papillomavirus Infection.

Exposures
- Exposure type: Tobacco.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EK-A3GK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 90 mg.
  Slide TCGA-EK-A3GK-01A-01-TSA: Section location: Top; Percent tumor cells: 96; Percent tumor nuclei: 96; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 2; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EK-A3GK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 0; Total pregnancy count: 0; Submitted tumor site: Cervical; Histologic diagnosis: Endocervical Type of Adenocarcinoma; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Radical hysterectomy, BSO, Bilateral pelvic LND, upper vaginectomy, omental and cecal biopsy; Lymph nodes examined: Yes; Lymphovascular invasion: Present; Corpus involvement: Absent.
- Human papillomavirus types: HPV types positive: HPV 16.
- Follow-up form: Lost to follow-up: Yes; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 15 days; disease-specific survival: no event (censored), 15 days; progression-free interval: no event (censored), 15 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EK-A3GK-01A-11D-A20T-01): tumor purity 0.85, ploidy 2.02, whole-genome doublings 0.
